Gene-level copy-number profile of tumor specimen TCGA-EI-6513-01A from TCGA case TCGA-EI-6513, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma in tubulovillous adenoma; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 59.6 years (21,776 days).
Specimen TCGA-EI-6513-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.19b63d43-8a52-41c5-bd31-17094bb35cb5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EI-6513-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/115d8354-da33-40b7-a309-efadb5df6699

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 10,774; copy number 2: 43,681; copy number 3: 3,246; copy number 4: 1,068; copy number 5: 1,029; copy number 6: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EI-6513-01A-21D-1732-01): tumor purity 0.84, ploidy 1.95, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:101,240,795–101,240,872, 1 gene: MIR8066.
- chr15:66,984,103–67,065,268, 1 gene (within-gene range 0–2): AC087482.1.
- chr15:77,420,412–77,485,607, 2 genes: HMG20A, AC090984.1.
- chr16:6,573,767–6,721,960, 3 genes: AC007223.1, AC007012.2, AC007012.1.
- chr18:36,297,714–36,780,055, 1 gene (within-gene range 0–1): FHOD3.
- chr18:36,777,647–36,829,216, 1 gene: TPGS2.
- chr18:36,901,946–36,923,814, 1 gene: AC016493.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,041 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:6,900,424–37,449,249, 485 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr7:37,419,628–65,554,744, 556 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 10,661. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
